Gene-level copy-number profile of tumor specimen TCGA-B2-5633-01B from TCGA case TCGA-B2-5633, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 56.1 years (20,493 days).
Specimen TCGA-B2-5633-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.35aa48cf-b684-48a9-80b6-83a0a0b75a62.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B2-5633-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate.
https://portal.gdc.cancer.gov/files/fd94e230-e87a-4ee4-9831-24224fa3ab81

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,406; copy number 2: 57,266; copy number 3: 527; copy number 4: 5; copy number 5: 58; copy number 7: 5; copy number 11: 2; copy number 13: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B2-5633-01A-01D-A274-01): tumor purity 0.55, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 66 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene, copy number 5: RPL31P12.
- chr2:88,857,161–89,046,466, 20 genes, copy number 5: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13.
- chr3:130,081,831–130,201,336, 5 genes, copy number 7 (within-gene range 2–7): ALG1L2, LINC02014, FAM86HP, LINC02021, ENPP7P3.
- chr4:154,754,756–154,781,873, 2 genes, copy number 5 (within-gene range 1–5): AC009567.1, AC009567.2.
- chr4:154,787,118–154,790,484, 2 genes, copy number 5: RNU2-66P, RNU2-44P.
- chr10:95,109,136–95,111,642, 1 gene, copy number 13: AL157834.1.
- chr13:48,316,863–48,328,564, 2 genes, copy number 11: PPP1R26P1, PCNPP5.
- chr15:25,172,635–25,232,468, 33 genes, copy number 5: SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34.

Autosomal genes at a single copy (total copy number 1): 22. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
